Gene-level copy-number profile of tumor specimen ALCH-B1WC-TTP1-A from ALCHEMIST case ALCH-B1WC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.2 years (26,381 days).
Specimen ALCH-B1WC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e608795-d4f7-477c-bb5e-cb4b477b9ac8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1WC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/aa987c02-39b3-4b16-b22a-38d2229b8dab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 4,306; copy number 2: 52,361; copy number 3: 1,468; copy number 4: 108; copy number 5: 85; copy number 6: 25; copy number 8: 1; copy number 9: 1; copy number 10: 1; copy number 11: 1; copy number 13: 1; copy number 16: 1; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,114,838–90,115,402, 1 gene (within-gene range 0–1): IGKV3D-15.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr2:91,578,478–91,659,972, 4 genes: AC233266.1, AC233266.2, AC116050.1, LSP1P4.
- chr2:232,479,827–232,487,834, 1 gene: ECEL1.
- chr4:188,159,705–188,161,157, 1 gene: LINC02434.
- chr8:144,698,614–144,699,185, 1 gene: AF186192.1.
- chr9:61,190,003–61,212,373, 4 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:61,642,383–61,666,386, 3 genes: Y_RNA, AL935212.1, AL935212.2.
- chr9:67,697,076–67,697,187, 1 gene: Y_RNA.
- chr10:132,961,340–132,962,237, 1 gene (within-gene range 0–1): LINC01167.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr16:89,921,392–89,938,761, 1 gene (within-gene range 0–5): TUBB3.
- chr16:90,004,871–90,019,890, 1 gene (within-gene range 0–1): DBNDD1.
- chr17:142,789–181,650, 1 gene: DOC2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,442,034–232,447,418, 1 gene, copy number 6: DIS3L2P1.
- chr3:190,428,655–190,659,750, 3 genes, copy number 5 (within-gene range 2–5): TMEM207, IL1RAP, GCNT1P3.
- chr12:56,822,985–58,395,138, 80 genes, copy number 5 (broad region; genes not listed).
- chr12:68,473,741–68,971,570, 22 genes, copy number 6: AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr14:104,677,694–104,677,749, 1 gene, copy number 8: MIR4710.
- chr14:104,800,596–104,804,712, 1 gene, copy number 16: ZBTB42.
- chr14:105,526,583–105,530,202, 1 gene, copy number 10: TMEM121.
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.
- chr16:991,151–1,000,926, 1 gene, copy number 6: AC009041.1.
- chr16:88,803,789–88,809,258, 1 gene, copy number 5: CDT1.
- chr19:984,332–1,009,732, 3 genes, copy number 6–11 (within-gene range 4–11): WDR18, AC004528.1, GRIN3B.
- chr19:1,228,287–1,239,522, 2 genes, copy number 13–22 (within-gene range 3–22): CBARP, AC004221.1.

Autosomal genes at a single copy (total copy number 1): 3,713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
